Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A5TY, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A5TY-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

ICD-3
Astrocytoma anaplastic
9401/3
Site CSE Supratentorial
path Brain NOS
C71.0
C71.9
JW 4/18/13

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age: Location: Received:
Gender: F Accnt: Reported:
Physician(s):
Phy Location:

Clinical History

Brain tumor

Operative Diagnoses

Operation / Specimen

A: Brain tumor, biopsy

B: Brain tumor, biopsy

Pathologic Diagnosis

A. and B. Brain, tumor, biopsies: Anaplastic astrocytoma, WHO grade III (see comment).

Comment

Permanent sections confirm the frozen section diagnosis and show a gemistocytic astrocytoma.

Intermingled with

nodules of medium large gemistocytes are areas of tightly packed, higher-grade pleomorphic astrocytoma nuclei with

indistinct cytoplasm. Mitotic figures are easily identified. Vascular proliferation and necrosis are not seen.

The tissue fragments are relatively small, therefore a higher-grade lesion, e.g. glioblastoma, WHO grade IV, cannot

be completely ruled out due to sampling phenomena. Clinical correlation is recommended.

The patient's tumor bank slide was also reviewed. Results of ancillary studies will be reported

below in

procedure addenda.

Electronically Signed Out

Senior Staff Pathologist

Procedures/Addenda

Immunohistology

Date Ordered:

Date Reported:

Interpretation

The tumor cells are diffusely GFAP and p53 positive.

The IDH1 R132H mutation is negative.

The Ki-67 labeling index is up to approximately 45%.

Surgical Pathology

Page 2 of 4

Results-Comments

Immunohistochemical stains are performed on A2. Controls show appropriate immunoreactivity.

Electronically Signed Out

Senior Staff Pathologist

PCR for EGFR variant III mutation

Date Ordered:

Date Reported:

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

[page 2 of 4]
TEST DESCRIPTION: Testing performed on RNA extracted from paraffin tissue block

(A2)

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma.

Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR

tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed,

paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR

technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay

has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test.

This test

was developed and its performance characteristics determined by the

as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These

results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Electronically Signed Out

MGMT Promoter Methylation

Date Ordered:

Date Reported:

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

(A2)

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification

of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

Surgical Pathology

Page 3 of 4

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the
as required

[page 3 of 4]
by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.
Electronically Signed Out

IDH1/IDH2 Mutation Detection Assay

Date Ordered:

Date Reported:

Interpretation

NEGATIVE - There is no evidence of IDH1 point mutation, as indicated by the absence of any nucleotide changes in codon 132 of the IDH1 gene compared to the electropherogram of the reference normal sample (wild type).

Results-Comments

TEST DESCRIPTION: IDH1/2 Mutation Analysis

Test performed on DNA extracted from tumor paraffin block (A2)

H and E slide was examined and no microdissection was needed.

Mutation of IDH1 occurs early in glioma progression with somatic mutations of the R132 residue of IDH1 identified in majority (>70%) of grades II and III astrocytomas and oligodendrogliomas, as well as in secondary GBMs that

developed from these lower grade lesions. Mutation analysis of closely related IDH2 revealed mutations of IDH2

residue R172, with most mutations occurring in tumors lacking IDH1 mutations. Tumors with IDH1 or IDH2 mutations

have distinctive genetic and clinical characteristics, and patients with such tumors have a better outcome than those

with wild type IDH genes.

Mutations in IDH1/2 are detected by DNA sequencing procedures. The limit of detection of standard bidirectional

sequencing is approximately 20-25%. In order to increase assay sensitivity tumor enrichment must be performed by

manual microdissection when tumor cells in the block constitute less than 50% of nucleated cells.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the

as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A. Brain tumor, biopsy: High-grade gemistocytic astrocytoma. Frozen section and smears performed at

and results reported to the Physician of Record.

Surgical Pathology

Page 4 of 4

Senior Staff Pathologist

[page 4 of 4]
Gross Description

A. Brain tumor, biopsy:

CONTAINER LABEL: brain tumor.

FIXATIVE: Formalin. NO. PIECES: few. SIZE/VOL: 10 x 8 x 4 mm. CASSETTES: 2, NS.

B. Brain tumor, biopsy: CONTAINER LABEL: brain tumor.

FIXATIVE: Formalin. NO. PIECES: 3 pieces of brain tissue. SIZE/VOL: 9x8x3 mm, 0.12gm in aggregate

CASSETTES: 1, NS.

ICD-9(s): 237.5 237.5

Billing Fee Code(s):

Histo Data**Part A: Brain tumor, biopsy**

Taken: Received:

Stain/cnt Block Ordered Comment

FS H&E x 1 1

H&E x 1 1

TPS H&E x 1 1

EGFR vIII-curIs x 1 2

mGFAP-DA x 1 2

Please run IDH1 antibody.

H&E x 1 2

MGMT-curIs x 1 2

Please run IDH1/2 mutational a

MIB1-DA x 1 2

P53DO7 x 1 2

Rct 1 H&E x 1 2

Part B: Brain tumor, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H&E x 1 1

Page 4 of 4

Source: NCI Genomic Data Commons file e6552435-a9b3-45e2-8b7f-98d5b13be91b (TCGA-DU-A5TY.70236BAA-BD1E-4AA3-A8D8-63F27289B160.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).